Somatic mutation profile of tumor specimen TCGA-V1-A9O5-01A (aliquot TCGA-V1-A9O5-01A-11D-A41K-08) from TCGA case TCGA-V1-A9O5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9O5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ae497b6-6724-4d1c-bd0c-1da16c527041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9O5-10A (Blood Derived Normal), aliquot TCGA-V1-A9O5-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e304cb01-4d13-46c7-afd3-56eb84a3ffa8

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.449del p.F150Sfs*15 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as rs1567817974; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 32/68 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF19 | c.1452C>T p.L484= | Splice Region (SNP) | VAF 3/14 reads (21%) | catalogued as rs1472531197, COSV99580875; called by muse, mutect2
- C8orf74 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.09); catalogued as rs374082262; called by muse, mutect2
- CPT1A | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99680880; called by muse, mutect2, varscan2
- FLG | c.8110A>G p.T2704A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV100912399; called by mutect2, varscan2
- ICAM1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs763975382, COSV99320665; called by muse, mutect2, varscan2
- IPO4 | c.2746C>T p.R916* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs767458231, COSV61016611; called by muse, mutect2, varscan2
- KDM2B | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1555288888, COSV100997712; called by muse, mutect2, varscan2
- KIFAP3 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100846844; called by muse, mutect2, varscan2
- NAT2 | c.156A>T p.L52F | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV99674023; called by muse, mutect2, varscan2
- NFIX | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs762562838, COSV62175797; called by muse, varscan2
- OSCAR | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99499895; called by muse, mutect2, varscan2
- PAPPA2 | c.2021A>G p.E674G | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100866693; called by muse, mutect2, varscan2
- PCSK4 | c.2177G>A p.G726D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV99961141; called by muse, mutect2
- PHC1 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV101418551; called by muse, mutect2, varscan2
- PLIN4 | c.1936G>A p.A646T (on ENST00000301286; = p.A661T on NM_001367868.2) | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as rs770863550, COSV56687875; called by muse, varscan2
- PYHIN1 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV100932543, COSV100932595, COSV63732699; called by muse, mutect2, varscan2
- SALL3 | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV73306707; called by muse, mutect2, varscan2
- SCRIB | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs1331834002, COSV100252910; called by muse, mutect2, varscan2
- STRN3 | c.2374C>A p.L792I (on ENST00000357479 / NM_001083893.2; = p.L708I on NM_014574.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100670473; called by muse, mutect2, varscan2
- TBXA2R | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1389139150, COSV64343669; called by muse, mutect2
- TTC7B | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as rs538272204, COSV60626174; called by muse, mutect2, varscan2
- WNK3 | c.2774A>G p.N925S | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100671092; called by muse, mutect2, varscan2
- ABCA13 | c.9719del p.G3240Vfs*6 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- CACNA1G | c.6733_6735del p.K2245del | In Frame Del (DEL) | VAF 10/39 reads (26%) | called by pindel, varscan2
- RERE | c.1246_1248del p.F416del | In Frame Del (DEL) | VAF 15/82 reads (18%) | called by pindel, varscan2
- TRAPPC8 | c.423del p.L142* | Frame Shift Del (DEL) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- DCAF8L1 | c.1752A>G p.S584= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as COSV101491431; called by muse, mutect2, varscan2
- EPPK1 | c.5499G>A p.T1833= | Silent (SNP) | VAF 259/384 reads (67%) | catalogued as rs1017044924, COSV101599791; called by muse, mutect2, varscan2
- PCNT | c.5952C>A p.A1984= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1427898325, COSV100856170; called by muse, mutect2, varscan2
- PPP1R1B | c.594C>A p.S198= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99566171; called by muse, mutect2, varscan2
- VRTN | c.*2A>G | 3'UTR (SNP) | VAF 14/44 reads (32%) | catalogued as rs1235339424, COSV99832184; called by muse, mutect2, varscan2
